CCDI case PBBXTS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/e5c96f81-1400-4f8c-b274-ca258afe1160

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Overlapping lesion of lung; Age at diagnosis: 0.3 years (103 days).

Biospecimens (3 samples)
- Sample 0DKV56: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKV57: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKV58: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
